Somatic mutation profile of tumor specimen TCGA-VD-A8KJ-01A (aliquot TCGA-VD-A8KJ-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KJ, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.6 years (19,562 days).
Specimen TCGA-VD-A8KJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b747d9d-a17b-4490-a847-1feaddbab44e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KJ-10A (Blood Derived Normal), aliquot TCGA-VD-A8KJ-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6233c2e-91ec-4a5b-be56-0baebbab080c

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.1079C>A p.S360* | Nonsense Mutation (SNP) | VAF 21/175 reads (12%) | catalogued as COSV67960995; called by muse, mutect2, varscan2
- PKHD1L1 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as COSV65736872, COSV65743471; called by muse, mutect2
- PRR19 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs139508954; called by muse, mutect2, varscan2
- UMOD | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs767780614, COSV56777798; called by muse, mutect2, varscan2
- ODC1 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- RGL3 | c.715dup p.Q239Pfs*115 | Frame Shift Ins (INS) | VAF 18/45 reads (40%) | called by muse*, mutect2, varscan2*
- STK33 | c.1304C>G p.P435R | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBP | c.195T>G p.T65= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
